Somatic mutation profile of tumor specimen MMRF_1461_1_BM_CD138pos (aliquot MMRF_1461_1_BM_CD138pos_T1_KAS5U_L01604) from MMRF case MMRF_1461, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.4 years (26,097 days).
Specimen MMRF_1461_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c833ce04-b744-4160-8085-23e39b83ec12.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1461_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1461_1_PB_Whole_C2_KAS5U_L01613; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9eed6b12-cb84-49af-93fe-47c4819ce852

The open-access MAF lists 278 somatic variants for this specimen: 98 protein-altering or splice-affecting, 42 silent, 138 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, 3'UTR 56, Intron 49, Silent 42, Nonsense Mutation 14, 3'Flank 9, 5'UTR 9, RNA 8, 5'Flank 7, Splice Region 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALMS1 | c.8005C>T p.R2669* | Nonsense Mutation (SNP) | VAF 113/275 reads (41%) | catalogued as rs549857076, CM050170, COSV52503066; ClinVar: pathogenic; called by muse, varscan2
- ACVR1C | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 225/461 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1267033436, COSV54648518; called by muse, mutect2, varscan2
- ANGPT2 | c.274C>T p.Q92* | Nonsense Mutation (SNP) | VAF 67/142 reads (47%) | catalogued as COSV57334713; called by muse, mutect2, varscan2
- AP3D1 | c.3388G>A p.D1130N | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs757744074; called by muse, mutect2, varscan2
- ATN1 | c.1769C>T p.P590L | Missense Mutation (SNP) | VAF 11/343 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs781790332; called by muse, mutect2
- BBS4 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as rs1567434989; called by muse, mutect2, varscan2
- CACNA1D | c.6140T>A p.F2047Y (on ENST00000350061 / NM_001128840.3; = p.F2067Y on NM_000720.4) | Missense Mutation (SNP) | VAF 104/223 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55440037; called by muse, mutect2, varscan2
- CALD1 | c.1519G>A p.E507K (on ENST00000361675 / NM_033138.4; = p.E252K on NM_004342.7) | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100724019; called by muse, mutect2, varscan2
- CNTN6 | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 67/138 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.426); catalogued as COSV100611636, COSV63160502; called by muse, mutect2, varscan2
- COL11A1 | c.1570C>T p.R524W | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs771139447, COSV62178322; called by muse, mutect2, varscan2
- DNAH5 | c.11377G>A p.E3793K | Missense Mutation (SNP) | VAF 101/212 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.168); catalogued as rs751996726, COSV54212253; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EGF | c.2458C>T p.Q820* | Nonsense Mutation (SNP) | VAF 55/132 reads (42%) | catalogued as COSV54478665; called by muse, mutect2, varscan2
- FBXL7 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 95/211 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs1286536913, COSV61642752; called by muse, mutect2, varscan2
- FLNB | c.1367G>T p.R456L | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.795); catalogued as rs377737248, COSV99912874; called by muse, mutect2, varscan2
- FOXL1 | c.887C>T p.S296L | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.273); catalogued as rs1206206480; called by muse, mutect2, varscan2
- GFPT1 | c.661C>T p.H221Y | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.74); PolyPhen benign (0.405); catalogued as COSV100622725; called by muse, mutect2, varscan2
- GJA8 | c.376C>T p.Q126* | Nonsense Mutation (SNP) | VAF 72/179 reads (40%) | catalogued as COSV53789729; called by muse, mutect2, varscan2
- GRIK4 | c.2599G>A p.A867T | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs766961901; called by muse, mutect2, varscan2
- IGKV4-1 | c.257A>G p.D86G | Missense Mutation (SNP) | VAF 38/38 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.709); catalogued as rs192839829; called by muse, varscan2
- IGKV4-1 | c.316G>C p.A106P | Missense Mutation (SNP) | VAF 40/40 reads (100%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.98); catalogued as rs188769218; called by muse, varscan2
- IGLV3-1 | c.308A>G p.D103G | Missense Mutation (SNP) | VAF 60/119 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs376677833; called by muse, varscan2
- IRF1 | c.311C>G p.S104* | Nonsense Mutation (SNP) | VAF 80/171 reads (47%) | catalogued as COSV55378672; called by muse, mutect2, varscan2
- MSH3 | c.1459C>G p.Q487E | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.061); catalogued as COSV54144313, COSV54163170; called by muse, mutect2, varscan2
- NIM1K | c.732C>G p.D244E | Missense Mutation (SNP) | VAF 9/160 reads (6%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.662); catalogued as COSV58140577, COSV58143671; called by muse, mutect2
- OR5R1 | c.503A>T p.Y168F | Missense Mutation (SNP) | VAF 66/140 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.246); catalogued as rs1477644741, COSV56573799; called by muse, mutect2
- PKD1 | c.12025G>A p.V4009M (on ENST00000262304 / NM_001009944.3; = p.V4008M on NM_000296.4) | Missense Mutation (SNP) | VAF 84/180 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.937); catalogued as rs749740699, COSV51921361; called by muse, mutect2, varscan2
- PKD1 | c.5992C>T p.R1998C | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs759346142; called by muse, mutect2, varscan2
- RARS2 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 73/118 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs201899366, COSV57638114, COSV57641021; called by muse, mutect2, varscan2
- RNFT2 | c.1246C>T p.R416C | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs374059009; called by muse, mutect2, varscan2
- RYR2 | c.13291G>T p.E4431* | Nonsense Mutation (SNP) | VAF 55/171 reads (32%) | catalogued as CM087242; called by muse, mutect2, varscan2
- SETMAR | c.1420G>C p.E474Q | Missense Mutation (SNP) | VAF 5/148 reads (3%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.771); catalogued as COSV99065518; called by muse, mutect2
- SLC8A3 | c.944A>G p.E315G | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as rs376894273; called by muse, mutect2, varscan2
- SMOC2 | c.641C>T p.S214L (on ENST00000356284 / NM_001166412.2; = p.S225L on NM_022138.3) | Missense Mutation (SNP) | VAF 65/115 reads (57%) | SIFT tolerated (0.68); PolyPhen benign (0.053); catalogued as rs1475770628, COSV62444788; called by muse, mutect2, varscan2
- TCN2 | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs200868221, COSV53192149; called by muse, mutect2, varscan2
- TET2 | c.4013A>C p.K1338T | Missense Mutation (SNP) | VAF 53/100 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54429496; called by muse, mutect2, varscan2
- THBS1 | c.1639C>T p.P547S | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1011847640; called by muse, mutect2, varscan2
- TULP2 | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 80/169 reads (47%) | catalogued as rs1197086158; called by muse, mutect2, varscan2
- UTP20 | c.6754G>C p.A2252P | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV55373906; called by muse, mutect2, varscan2
- VWCE | c.475G>T p.E159* | Nonsense Mutation (SNP) | VAF 29/73 reads (40%) | catalogued as COSV57111105; called by muse, mutect2, varscan2
- ZDHHC20 | c.642C>G p.F214L | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.957); catalogued as rs1318733588; called by muse, mutect2, varscan2
- ZFP3 | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV59582910; called by muse, mutect2, varscan2
- ZNF737 | c.1454G>A p.R485Q | Missense Mutation (SNP) | VAF 66/173 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs371460168, COSV101417642; called by muse, mutect2, varscan2
- ACAP3 | c.778G>C p.E260Q | Missense Mutation (SNP) | VAF 81/172 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- ARHGAP6 | c.1120C>G p.Q374E | Missense Mutation (SNP) | VAF 45/45 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- CCN6 | c.388C>T p.H130Y | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- CUBN | c.6133A>G p.N2045D | Missense Mutation (SNP) | VAF 70/159 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CUL9 | c.354T>A p.D118E | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- DHX30 | c.760C>T p.Q254* (on ENST00000445061 / NM_138615.3; = p.Q215* on NM_014966.3) | Nonsense Mutation (SNP) | VAF 32/68 reads (47%) | called by muse, mutect2, varscan2
- DIS3 | c.1207G>A p.D403N | Missense Mutation (SNP) | VAF 78/93 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DUOX2 | c.3908T>C p.V1303A | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ELMOD1 | c.518T>A p.F173Y | Missense Mutation (SNP) | VAF 59/216 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM126A | c.973C>T p.H325Y | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FCGR2B | c.392-3C>T | Splice Region (SNP) | VAF 18/58 reads (31%) | called by muse, varscan2
- H2BC6 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 83/191 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- HMGB1 | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 5/42 reads (12%) | called by muse, mutect2, varscan2
- ISM1 | c.1378G>C p.E460Q | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- KCNB1 | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- KIF20B | c.3556G>A p.D1186N (on ENST00000371728 / NM_001284259.2; = p.D1146N on NM_016195.4) | Missense Mutation (SNP) | VAF 52/106 reads (49%) | SIFT tolerated (0.42); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- KRIT1 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2
- LAMB2 | c.2164C>T p.P722S | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LNX2 | c.1670T>C p.I557T | Missense Mutation (SNP) | VAF 64/64 reads (100%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGEB1 | c.69G>C p.Q23H | Missense Mutation (SNP) | VAF 65/79 reads (82%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- MDGA2 | c.488C>A p.T163N | Missense Mutation (SNP) | VAF 59/115 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MIPOL1 | c.828G>T p.K276N | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.165); called by muse, mutect2
- MPP3 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO5A | c.3691G>T p.E1231* | Nonsense Mutation (SNP) | VAF 23/60 reads (38%) | called by muse, mutect2, varscan2
- NCOA1 | c.3301C>T p.Q1101* | Nonsense Mutation (SNP) | VAF 117/296 reads (40%) | called by muse, mutect2, varscan2
- NCOR2 | c.5543C>T p.P1848L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- NOVA2 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.7); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OSBPL1A | c.109A>T p.I37F | Missense Mutation (SNP) | VAF 97/196 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PAK2 | c.1283C>G p.S428C | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLXNA2 | c.1882C>T p.Q628* | Nonsense Mutation (SNP) | VAF 39/148 reads (26%) | called by muse, mutect2, varscan2
- RSC1A1 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 64/147 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- SEMA7A | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 92/198 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SETD6 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SLC12A4 | c.1727T>C p.M576T | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SMOC2 | c.198del p.Q67Nfs*10 | Frame Shift Del (DEL) | VAF 32/77 reads (42%) | called by mutect2, pindel, varscan2
- SMYD1 | c.791G>A p.R264K | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- SOGA1 | c.4939G>C p.E1647Q | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- SORCS2 | c.2090G>T p.R697L | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- SREBF2 | c.2602C>A p.L868M | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- STAT3 | c.923G>T p.R308I | Missense Mutation (SNP) | VAF 96/201 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- STAT4 | c.829G>T p.E277* | Nonsense Mutation (SNP) | VAF 66/168 reads (39%) | called by muse, mutect2, varscan2
- SYS1 | c.150G>T p.M50I | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TGDS | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 36/44 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TGDS | c.325G>C p.V109L | Missense Mutation (SNP) | VAF 49/49 reads (100%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TPI1 | c.164G>A p.R55Q (on ENST00000229270; = p.R18Q on NM_000365.6) | Missense Mutation (SNP) | VAF 78/168 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TPP2 | c.1073C>T p.S358L | Missense Mutation (SNP) | VAF 39/44 reads (89%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- TPTE2 | c.1265A>G p.K422R (on ENST00000400230 / NM_199254.2; = p.K345R on NM_130785.3) | Missense Mutation (SNP) | VAF 47/54 reads (87%) | SIFT tolerated (0.2); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TXNRD1 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP36 | c.2428G>A p.E810K | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VARS1 | c.3301G>T p.D1101Y | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- VLDLR | c.2415C>A p.L805= | Splice Region (SNP) | VAF 21/47 reads (45%) | called by muse, mutect2, varscan2
- VWDE | c.1058C>T p.S353F | Missense Mutation (SNP) | VAF 54/137 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- XPR1 | c.1427A>G p.H476R | Missense Mutation (SNP) | VAF 41/71 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF704 | c.326-1G>A p.X109_splice | Splice Site (SNP) | VAF 15/31 reads (48%) | called by muse, mutect2, varscan2
- ZNF831 | c.1049C>A p.S350Y | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF93 | c.593A>G p.E198G | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- ADAMTS14 | c.3483G>C p.G1161= | Silent (SNP) | VAF 10/296 reads (3%) | catalogued as rs1234445325; called by muse, mutect2
- AGXT2 | c.855C>T p.F285= | Silent (SNP) | VAF 103/189 reads (54%) | catalogued as rs533299831, COSV51483829; called by muse, mutect2, varscan2
- C7orf33 | c.321G>A p.Q107= | Silent (SNP) | VAF 37/85 reads (44%) | called by muse, mutect2, varscan2
- CCDC168 | c.8535A>C p.V2845= | Silent (SNP) | VAF 77/84 reads (92%) | called by muse, mutect2, varscan2
- CCDC88C | c.12A>T p.T4= | Silent (SNP) | VAF 19/47 reads (40%) | called by muse, mutect2, varscan2
- CCNF | c.1467C>T p.V489= | Silent (SNP) | VAF 89/179 reads (50%) | called by muse, mutect2, varscan2
- CLTCL1 | c.351C>T p.N117= | Silent (SNP) | VAF 55/104 reads (53%) | called by muse, mutect2, varscan2
- CSMD1 | c.6627G>A p.Q2209= (on ENST00000520002; = p.Q2208= on NM_033225.6) | Silent (SNP) | VAF 35/59 reads (59%) | catalogued as COSV59311938; called by muse, mutect2, varscan2
- DNAH1 | c.7014C>T p.N2338= | Silent (SNP) | VAF 70/139 reads (50%) | called by muse, mutect2, varscan2
- DUS2 | c.22C>T p.L8= | Silent (SNP) | VAF 77/156 reads (49%) | called by muse, mutect2, varscan2
- ERAP1 | c.750C>A p.I250= | Silent (SNP) | VAF 163/368 reads (44%) | catalogued as rs370818718; called by muse, mutect2, varscan2
- FBN2 | c.8421C>T p.F2807= | Silent (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2, varscan2
- FOXD1 | c.39C>T p.L13= | Silent (SNP) | VAF 26/51 reads (51%) | catalogued as rs1487535826; called by muse, mutect2, varscan2
- FOXN4 | c.690C>T p.F230= | Silent (SNP) | VAF 34/81 reads (42%) | called by muse, mutect2, varscan2
- FSIP2 | c.3528C>T p.N1176= | Silent (SNP) | VAF 6/118 reads (5%) | catalogued as rs1340447706; called by muse, mutect2
- IGHV2-70 | c.138C>T p.F46= | Silent (SNP) | VAF 57/105 reads (54%) | catalogued as rs374979633; called by muse, mutect2, varscan2
- ITPR3 | c.6054C>T p.I2018= | Silent (SNP) | VAF 37/74 reads (50%) | called by muse, mutect2, varscan2
- KLF7 | c.738G>A p.E246= | Silent (SNP) | VAF 77/165 reads (47%) | called by muse, mutect2, varscan2
- LEPR | c.1204C>A p.R402= | Silent (SNP) | VAF 32/71 reads (45%) | catalogued as COSV60759159; called by muse, mutect2, varscan2
- MCM3AP | c.3768G>C p.L1256= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as COSV52437130; called by muse, mutect2, varscan2
- MX2 | c.1752T>C p.I584= | Silent (SNP) | VAF 89/190 reads (47%) | called by muse, mutect2, varscan2
- NPAP1 | c.1221C>A p.T407= | Silent (SNP) | VAF 132/269 reads (49%) | catalogued as COSV61510961; called by muse, mutect2
- NUTM1 | c.2808G>A p.V936= | Silent (SNP) | VAF 34/82 reads (41%) | called by muse, mutect2, varscan2
- PAQR8 | c.360C>T p.I120= | Silent (SNP) | VAF 81/217 reads (37%) | catalogued as rs1485007788; called by muse, mutect2, varscan2
- PPP1R13B | c.309G>A p.Q103= | Silent (SNP) | VAF 126/324 reads (39%) | catalogued as COSV52450205; called by muse, mutect2, varscan2
- PRCP | c.1455C>T p.I485= | Silent (SNP) | VAF 38/89 reads (43%) | called by muse, mutect2
- PRMT7 | c.1185G>A p.L395= | Silent (SNP) | VAF 50/124 reads (40%) | called by muse, mutect2, varscan2
- PTGDR2 | c.858G>A p.L286= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as rs1375979636; called by muse, mutect2, varscan2
- PTPRF | c.3462C>T p.P1154= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as rs145265549, COSV100740554; called by muse, mutect2, varscan2
- QPRT | c.492G>A p.L164= | Silent (SNP) | VAF 36/79 reads (46%) | called by muse, mutect2, varscan2
- RNF220 | c.630G>A p.K210= | Silent (SNP) | VAF 77/154 reads (50%) | catalogued as COSV62404503; called by muse, mutect2, varscan2
- RPAP1 | c.3849C>A p.L1283= | Silent (SNP) | VAF 43/86 reads (50%) | called by muse, mutect2, varscan2
- RTN4RL1 | c.813G>A p.Q271= | Silent (SNP) | VAF 20/43 reads (47%) | called by muse, mutect2, varscan2
- SDR42E2 | c.1032G>A p.V344= | Silent (SNP) | VAF 44/90 reads (49%) | called by muse, varscan2
- SLC14A2 | c.369G>A p.L123= | Silent (SNP) | VAF 8/16 reads (50%) | called by muse, mutect2, varscan2
- SLC4A2 | c.2418C>G p.L806= | Silent (SNP) | VAF 49/114 reads (43%) | called by muse, mutect2, varscan2
- SUSD5 | c.1365C>T p.S455= | Silent (SNP) | VAF 35/103 reads (34%) | catalogued as rs773323669, COSV100535050; called by muse, mutect2, varscan2
- TBC1D23 | c.525C>A p.I175= | Silent (SNP) | VAF 29/84 reads (35%) | called by muse, mutect2, varscan2
- TCF7L1 | c.501G>A p.T167= | Silent (SNP) | VAF 144/280 reads (51%) | catalogued as rs756692433; called by muse, mutect2, varscan2
- TENM2 | c.426C>T p.S142= | Silent (SNP) | VAF 76/146 reads (52%) | called by muse, mutect2, varscan2
- U2SURP | c.1290G>C p.L430= | Silent (SNP) | VAF 239/882 reads (27%) | catalogued as rs772790867; called by muse, mutect2, varscan2
- ZNF488 | c.658T>C p.L220= | Silent (SNP) | VAF 75/157 reads (48%) | catalogued as rs782630783; called by muse, mutect2, varscan2
- ABCA1 | c.*1648C>G | 3'UTR (SNP) | VAF 92/191 reads (48%) | called by muse, mutect2, varscan2
- ABCD4 | chr14:74303045 C>G | 5'Flank (SNP) | VAF 82/155 reads (53%) | called by muse, mutect2, varscan2
- AC022182.2 | n.32T>G | RNA (SNP) | VAF 46/105 reads (44%) | called by muse, mutect2, varscan2
- AC122719.2 | n.258T>G | RNA (SNP) | VAF 21/51 reads (41%) | called by muse, mutect2, varscan2
- ACAD8 | c.1093-301G>A | Intron (SNP) | VAF 21/67 reads (31%) | catalogued as COSV99844713; called by muse, mutect2, varscan2
- ACSM5P1 | n.1353C>A | RNA (SNP) | VAF 5/9 reads (56%) | called by muse, mutect2, varscan2
- ACSS1 | c.*458C>T | 3'UTR (SNP) | VAF 31/73 reads (42%) | catalogued as rs926503083; called by muse, mutect2, varscan2
- ANO3 | c.*2420G>A | 3'UTR (SNP) | VAF 54/112 reads (48%) | called by muse, mutect2, varscan2
- AP002748.5 | c.*423C>T | 3'UTR (SNP) | VAF 57/124 reads (46%) | called by muse, mutect2, varscan2
- ATE1 | c.*273C>T | 3'UTR (SNP) | VAF 56/112 reads (50%) | called by muse, mutect2, varscan2
- ATF2 | c.-143+343T>G | Intron (SNP) | VAF 48/81 reads (59%) | called by muse, mutect2, varscan2
- ATP6V1B2 | c.1162-9C>T | Intron (SNP) | VAF 35/90 reads (39%) | called by muse, mutect2, varscan2
- BCL9L | c.*729G>A | 3'UTR (SNP) | VAF 5/88 reads (6%) | catalogued as rs1161377693; called by muse, mutect2
- BRIX1 | c.*432G>A | 3'UTR (SNP) | VAF 11/182 reads (6%) | called by muse, mutect2
- C11orf86 | c.*255C>A | 3'UTR (SNP) | VAF 48/89 reads (54%) | called by muse, mutect2, varscan2
- CACNA1S | c.*235C>G | 3'UTR (SNP) | VAF 51/151 reads (34%) | called by muse, mutect2, varscan2
- CALU | c.-11-945C>T | Intron (SNP) | VAF 27/64 reads (42%) | called by muse, mutect2, varscan2
- CCDC24 | c.-33+38G>T | Intron (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- CCDC90B | chr11:83255970 del C | 3'Flank (DEL) | VAF 48/130 reads (37%) | called by pindel, varscan2
- CCDC90B | chr11:83256051 C>T | 3'Flank (SNP) | VAF 62/114 reads (54%) | called by muse, varscan2
- CCHCR1 | c.-51-147C>T | Intron (SNP) | VAF 298/644 reads (46%) | called by muse, mutect2, varscan2
- CDC27 | c.*841C>G | 3'UTR (SNP) | VAF 47/97 reads (48%) | catalogued as rs771110019; called by muse, mutect2, varscan2
- CEP70 | c.*661G>C | 3'UTR (SNP) | VAF 53/83 reads (64%) | called by muse, mutect2, varscan2
- CHRNA7 | c.196-495C>T | Intron (SNP) | VAF 9/18 reads (50%) | catalogued as rs1566838493; called by muse, mutect2, varscan2
- CSNK1A1 | c.230+722C>G | Intron (SNP) | VAF 92/220 reads (42%) | called by muse, mutect2, varscan2
- CSNK1A1L | c.*5G>A | 3'UTR (SNP) | VAF 147/170 reads (86%) | called by muse, mutect2, varscan2
- DCUN1D4 | c.*3203G>A | 3'UTR (SNP) | VAF 4/68 reads (6%) | called by muse, mutect2
- DDR1 | c.-98-302C>G | Intron (SNP) | VAF 24/54 reads (44%) | called by muse, mutect2, varscan2
- DNAJB2 | c.-36-11C>G | Intron (SNP) | VAF 42/86 reads (49%) | catalogued as rs777721294; ClinVar: likely benign; called by muse, mutect2, varscan2
- DOCK1 | c.1561+44G>A | Intron (SNP) | VAF 38/72 reads (53%) | called by muse, mutect2, varscan2
- EIF5AL1 | c.*3315G>A | 3'UTR (SNP) | VAF 60/117 reads (51%) | called by muse, mutect2, varscan2
- ELAVL2 | chr9:23690806 C>T | 3'Flank (SNP) | VAF 20/58 reads (34%) | catalogued as COSV99805166; called by muse, mutect2, varscan2
- EOMES | c.*214G>A | 3'UTR (SNP) | VAF 25/46 reads (54%) | called by muse, mutect2, varscan2
- ERBB4 | c.*1131T>A | 3'UTR (SNP) | VAF 47/92 reads (51%) | called by muse, mutect2, varscan2
- ETV3 | c.400+561A>G | Intron (SNP) | VAF 41/149 reads (28%) | called by muse, mutect2, varscan2
- FAM120A | c.1734+354C>T | Intron (SNP) | VAF 66/137 reads (48%) | called by muse, mutect2, varscan2
- FAP | c.1870-91C>T | Intron (SNP) | VAF 15/38 reads (39%) | called by muse, mutect2, varscan2
- FKBP4 | c.-156C>T | 5'UTR (SNP) | VAF 43/109 reads (39%) | called by muse, mutect2, varscan2
- FTCDNL1 | c.*135C>T | 3'UTR (SNP) | VAF 24/54 reads (44%) | called by muse, mutect2, varscan2
- GALNT10 | c.1056+2241G>A | Intron (SNP) | VAF 51/142 reads (36%) | called by muse, mutect2, varscan2
- GAPVD1 | chr9:125365020 C>G | 3'Flank (SNP) | VAF 35/84 reads (42%) | called by muse, mutect2, varscan2
- GLRA2 | c.-431C>G | 5'UTR (SNP) | VAF 5/65 reads (8%) | called by muse, mutect2
- GMPPB | chr3:49717132 G>A | 3'Flank (SNP) | VAF 51/125 reads (41%) | called by muse, mutect2, varscan2
- GPATCH2L | c.*890C>T | 3'UTR (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- GPI | c.865+116C>T | Intron (SNP) | VAF 22/64 reads (34%) | catalogued as rs972276609; called by muse, mutect2
- GRK6 | c.-45C>T | 5'UTR (SNP) | VAF 8/20 reads (40%) | called by muse, varscan2
- GUCY1A2 | c.1207-14401C>T | Intron (SNP) | VAF 126/333 reads (38%) | called by muse, mutect2, varscan2
- GUCY2C | c.*291C>G | 3'UTR (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2
- GULP1 | c.843+2203T>G | Intron (SNP) | VAF 9/17 reads (53%) | called by muse, mutect2, varscan2
- GYPB | c.37+2384G>T | Intron (SNP) | VAF 60/140 reads (43%) | called by muse, mutect2, varscan2
- GZF1 | c.*496C>T | 3'UTR (SNP) | VAF 48/98 reads (49%) | called by muse, mutect2, varscan2
- HMGA2 | c.249+20072G>A | Intron (SNP) | VAF 58/115 reads (50%) | called by muse, mutect2, varscan2
- HNF4G | chr8:75564946 G>C | 3'Flank (SNP) | VAF 47/105 reads (45%) | called by muse, mutect2, varscan2
- HRH2 | chr5:175682953 C>T | 5'Flank (SNP) | VAF 34/73 reads (47%) | called by muse, mutect2, varscan2
- IGHV3-23 | c.-47T>C | 5'UTR (SNP) | VAF 43/156 reads (28%) | catalogued as rs782724847; called by muse, mutect2, varscan2
- INHBE | c.*58G>A | 3'UTR (SNP) | VAF 14/128 reads (11%) | catalogued as COSV99875387; called by muse, mutect2, varscan2
- IPO8 | c.84+501G>A | Intron (SNP) | VAF 166/329 reads (50%) | called by muse, mutect2, varscan2
- ITGA7 | c.803-101C>T | Intron (SNP) | VAF 16/26 reads (62%) | catalogued as rs1385885702; called by muse, mutect2, varscan2
- ITSN1 | c.*4329C>G | 3'UTR (SNP) | VAF 35/73 reads (48%) | called by muse, mutect2, varscan2
- KIAA1549L | chr11:33542255 C>T | 5'Flank (SNP) | VAF 81/190 reads (43%) | called by muse, mutect2, varscan2
- KIF21A | chr12:39443246 G>C | 5'Flank (SNP) | VAF 24/50 reads (48%) | catalogued as rs1352404640; called by muse, mutect2, varscan2
- KIF5C | c.714+900G>T | Intron (SNP) | VAF 58/204 reads (28%) | called by muse, mutect2, varscan2
- KLF4 | c.1099+39T>A | Intron (SNP) | VAF 82/211 reads (39%) | called by muse, mutect2, varscan2
- KLRF2 | chr12:9898956 G>C | 3'Flank (SNP) | VAF 27/76 reads (36%) | called by muse, mutect2, varscan2
- LGI2 | c.*2706G>A | 3'UTR (SNP) | VAF 27/79 reads (34%) | catalogued as rs1234290467; called by muse, mutect2, varscan2
- LINC00636 | n.953G>A | RNA (SNP) | VAF 41/109 reads (38%) | called by muse, mutect2, varscan2
- LINC02693 | n.5991G>C | RNA (SNP) | VAF 39/93 reads (42%) | called by muse, mutect2, varscan2
- LRRC29 | c.-134-661C>G | Intron (SNP) | VAF 62/116 reads (53%) | called by muse, mutect2, varscan2
- MAFB | c.*1338G>A | 3'UTR (SNP) | VAF 22/42 reads (52%) | called by muse, mutect2, varscan2
- MAFB | c.*1070G>A | 3'UTR (SNP) | VAF 19/45 reads (42%) | catalogued as rs961204294; called by muse, mutect2, varscan2
- MAFB | c.*956G>C | 3'UTR (SNP) | VAF 26/61 reads (43%) | called by muse, mutect2, varscan2
- MAU2 | c.1639+80C>T | Intron (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2, varscan2
- MCTP1 | c.*1528G>A | 3'UTR (SNP) | VAF 31/82 reads (38%) | called by muse, mutect2, varscan2
- MCTP1 | c.1212+49T>C | Intron (SNP) | VAF 74/133 reads (56%) | called by muse, mutect2, varscan2
- MECR | c.*53G>A | 3'UTR (SNP) | VAF 29/62 reads (47%) | catalogued as rs1247159505; called by muse, mutect2, varscan2
- MED28 | c.*8241G>A | 3'UTR (SNP) | VAF 24/51 reads (47%) | called by mutect2, varscan2
- MKRN2 | c.26+94G>C | Intron (SNP) | VAF 14/51 reads (27%) | called by muse, mutect2, varscan2
- MMP11 | c.*465G>A | 3'UTR (SNP) | VAF 41/107 reads (38%) | called by muse, mutect2, varscan2
- MOG | c.730+188A>T | Intron (SNP) | VAF 21/234 reads (9%) | called by muse, mutect2
- MUC20P1 | n.861C>A | RNA (SNP) | VAF 14/47 reads (30%) | called by muse, varscan2
- MX1 | c.-21-131G>A | Intron (SNP) | VAF 57/126 reads (45%) | called by muse, mutect2, varscan2
- NDST3 | c.*2079G>A | 3'UTR (SNP) | VAF 13/162 reads (8%) | called by muse, mutect2
- NDUFC1 | c.-119G>A | 5'UTR (SNP) | VAF 61/158 reads (39%) | catalogued as COSV99643927; called by muse, mutect2, varscan2
- NFS1 | c.*770C>G | 3'UTR (SNP) | VAF 35/71 reads (49%) | called by muse, mutect2, varscan2
- NIP7 | c.423+76G>C | Intron (SNP) | VAF 29/62 reads (47%) | called by muse, mutect2, varscan2
- NOS2 | c.*398C>T | 3'UTR (SNP) | VAF 19/412 reads (5%) | called by muse, mutect2
- NR5A1 | c.*621G>C | 3'UTR (SNP) | VAF 41/87 reads (47%) | called by muse, mutect2, varscan2
- NSG2 | c.*1233C>T | 3'UTR (SNP) | VAF 24/54 reads (44%) | called by muse, mutect2
- P2RX5 | c.*470T>G | 3'UTR (SNP) | VAF 64/143 reads (45%) | called by muse, mutect2, varscan2
- PARM1 | c.-200A>G | 5'UTR (SNP) | VAF 32/57 reads (56%) | called by muse, mutect2, varscan2
- PAX2 | chr10:100745676 C>T | 5'Flank (SNP) | VAF 50/97 reads (52%) | called by muse, mutect2, varscan2
- PCDH11X | c.*2898A>T | 3'UTR (SNP) | VAF 132/132 reads (100%) | called by muse, varscan2
- PCDH11X | c.*2910T>A | 3'UTR (SNP) | VAF 118/118 reads (100%) | called by muse, varscan2
- PDE4D | c.456-1301C>A | Intron (SNP) | VAF 14/32 reads (44%) | called by muse, mutect2, varscan2
- PDE8B | c.*709T>A | 3'UTR (SNP) | VAF 30/70 reads (43%) | called by muse, mutect2, varscan2
- PEX19 | c.*2491G>A | 3'UTR (SNP) | VAF 32/137 reads (23%) | called by muse, mutect2, varscan2
- PGAP2 | c.525+297G>A | Intron (SNP) | VAF 11/20 reads (55%) | called by muse, mutect2, varscan2
- PHACTR1 | c.1510-1902G>A | Intron (SNP) | VAF 24/52 reads (46%) | called by muse, mutect2, varscan2
- PLXNB1 | c.*97G>A | 3'UTR (SNP) | VAF 72/168 reads (43%) | called by muse, mutect2, varscan2
- PNISR | c.1157-70C>T | Intron (SNP) | VAF 23/60 reads (38%) | called by muse, mutect2, varscan2
- PPDPFL | c.*804C>A | 3'UTR (SNP) | VAF 53/112 reads (47%) | catalogued as COSV100293026, COSV100293098; called by muse, mutect2, varscan2
- PPP1R18 | chr6:30686803 C>A | 5'Flank (SNP) | VAF 29/64 reads (45%) | called by muse, mutect2, varscan2
- PROC | c.*181C>G | 3'UTR (SNP) | VAF 30/73 reads (41%) | called by muse, mutect2, varscan2
- PSIP1 | c.-93G>C | 5'UTR (SNP) | VAF 10/18 reads (56%) | called by muse, varscan2
- PSMC2 | c.*58G>T | 3'UTR (SNP) | VAF 192/375 reads (51%) | called by muse, mutect2, varscan2
- PSMG3-AS1 | n.3338C>A | RNA (SNP) | VAF 33/79 reads (42%) | called by muse, mutect2, varscan2
- RBM20 | c.*1670G>A | 3'UTR (SNP) | VAF 31/84 reads (37%) | called by muse, mutect2, varscan2
- REXO1 | c.2527-25C>T | Intron (SNP) | VAF 32/72 reads (44%) | catalogued as rs762901808; called by muse, mutect2, varscan2
- RNF10 | c.-283C>T | 5'UTR (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- RPL27A | c.*2352G>C | 3'UTR (SNP) | VAF 64/147 reads (44%) | catalogued as rs373036436; called by muse, mutect2, varscan2
- SCUBE1 | c.844+207G>A | Intron (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2, varscan2
- SELENOW | c.30-10C>G | Intron (SNP) | VAF 36/66 reads (55%) | called by muse, mutect2, varscan2
- SEPTIN9 | c.722-36170C>G | Intron (SNP) | VAF 39/94 reads (41%) | called by muse, mutect2, varscan2
- SERPINA9 | chr14:94476214 C>T | 5'Flank (SNP) | VAF 341/802 reads (43%) | called by muse, mutect2, varscan2
- SF1 | c.236+32dup | Intron (INS) | VAF 32/97 reads (33%) | called by mutect2, pindel, varscan2
- SHROOM3 | c.*2049C>G | 3'UTR (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2
- SLC4A7 | c.*2276C>T | 3'UTR (SNP) | VAF 63/141 reads (45%) | called by muse, mutect2, varscan2
- SLTM | c.2996+74C>G | Intron (SNP) | VAF 14/34 reads (41%) | called by muse, mutect2
- SMG7 | c.30-10559G>C | Intron (SNP) | VAF 149/335 reads (44%) | called by muse, mutect2, varscan2
- SNAPC2 | c.184-57C>T | Intron (SNP) | VAF 45/94 reads (48%) | called by muse, mutect2, varscan2
- SSR1 | c.*3325G>C | 3'UTR (SNP) | VAF 54/113 reads (48%) | called by muse, mutect2, varscan2
- ST6GAL2 | c.*185A>T | 3'UTR (SNP) | VAF 21/46 reads (46%) | called by muse, mutect2, varscan2
- STAT3 | c.1109+68C>T | Intron (SNP) | VAF 22/53 reads (42%) | called by muse, mutect2, varscan2
- SWT1 | c.*903C>G | 3'UTR (SNP) | VAF 21/55 reads (38%) | catalogued as COSV100832846; called by muse, mutect2, varscan2
- TANC1 | c.3503-29C>T | Intron (SNP) | VAF 27/68 reads (40%) | called by muse, mutect2, varscan2
- TAT | c.*727C>T | 3'UTR (SNP) | VAF 26/64 reads (41%) | called by muse, mutect2, varscan2
- TMEM263 | c.*1714T>G | 3'UTR (SNP) | VAF 81/156 reads (52%) | called by muse, mutect2, varscan2
- TMEM59 | c.*427G>A | 3'UTR (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- TOMM70 | c.1092+92C>G | Intron (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2
- TP53RK | c.*1287C>A | 3'UTR (SNP) | VAF 24/62 reads (39%) | catalogued as rs937457227; called by muse, mutect2, varscan2
- TRIM67 | chr1:231220382 C>T | 3'Flank (SNP) | VAF 66/177 reads (37%) | called by muse, mutect2, varscan2
- TRPM8 | c.1362+46A>C | Intron (SNP) | VAF 23/39 reads (59%) | called by muse, mutect2, varscan2
- TSPAN31 | c.*10T>C | 3'UTR (SNP) | VAF 46/97 reads (47%) | called by muse, mutect2, varscan2
- UBE2V2 | c.17-347C>G | Intron (SNP) | VAF 37/98 reads (38%) | called by muse, mutect2, varscan2
- VSX2 | c.-73G>A | 5'UTR (SNP) | VAF 30/68 reads (44%) | called by muse, mutect2, varscan2
- WDR17 | chr4:176181903 G>C | 3'Flank (SNP) | VAF 48/88 reads (55%) | called by muse, mutect2, varscan2
- ZFC3H1 | c.5729+63G>C | Intron (SNP) | VAF 6/16 reads (38%) | called by muse, varscan2
- ZNF204P | n.808G>A | RNA (SNP) | VAF 21/67 reads (31%) | called by muse, mutect2, varscan2
